Gene-level copy-number profile of tumor specimen TCGA-61-2092-01A from TCGA case TCGA-61-2092, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 57.7 years (21,072 days).
Specimen TCGA-61-2092-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.8c29ee0e-c6d1-412a-93c3-9bc90c22b16d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-2092-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/39094cdf-09e4-4085-b882-3c1c8bf73e1c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 624; copy number 2: 53,617; copy number 3: 5,331; copy number 4: 217; copy number 5: 11; copy number 6: 8; copy number 8: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-61-2092-01A-01D-0663-01): tumor purity 0.93, ploidy 2.08, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 21 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:30,810,378–30,918,735, 6 genes, copy number 6: AL137027.1, LINC01778, RN7SKP91, AL445235.1, SDC3, RN7SL371P.
- chr3:106,684,388–106,691,320, 2 genes, copy number 6: AC080097.1, Y_RNA.
- chr3:177,621,382–177,628,287, 2 genes, copy number 8: AC026355.3, AC026355.1.
- chr9:83,817,643–84,098,984, 11 genes, copy number 5: AL354733.1, AL354733.2, KIF27, C9orf64, HNRNPK, MIR7-1, AL354733.3, RMI1, Y_RNA, AL390838.1, AL390838.2.

Autosomal genes at a single copy (total copy number 1): 624. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
